Gene-level copy-number profile of tumor specimen ALCH-AE5P-TTP1-A from ALCHEMIST case ALCH-AE5P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,774 days).
Specimen ALCH-AE5P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04c7efde-9c35-4a24-9465-8a7d70675106.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE5P-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/2deaff62-ba68-4251-842d-f01e06a3d09f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,948; copy number 2: 54,971; copy number 3: 985; copy number 4: 6; copy number 7: 3; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,636,356–248,645,278, 1 gene, copy number 8: OR2T35.
- chr10:87,357,720–87,370,695, 1 gene, copy number 8 (within-gene range 3–8): NUTM2D.
- chr22:18,906,028–18,947,732, 3 genes, copy number 7 (within-gene range 2–7): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 93. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
